Somatic mutation profile of tumor specimen MP2PRT-PASTZJ-TBP1-A (aliquot MP2PRT-PASTZJ-TBP1-A-1-0-D-A835-36) from MP2PRT case MP2PRT-PASTZJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,765 days).
Specimen MP2PRT-PASTZJ-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2e9b9b0-c7ba-45b4-ab44-543ccb2cf4ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASTZJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASTZJ-NB1-A-1-0-D-A835-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d241ad95-dd7f-41de-bf24-bcaa2b5393be

The open-access MAF lists 27 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 4, Splice Site 1, Frame Shift Ins 1, Splice Region 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSS3 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 56/278 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs147777981, COSV54088446; called by muse, varscan2
- AHNAK2 | c.468G>A p.G156= | Splice Region (SNP) | VAF 55/240 reads (23%) | catalogued as rs200286499; called by muse, mutect2, varscan2
- JAK1 | c.1954T>C p.Y652H | Missense Mutation (SNP) | VAF 111/631 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.478); catalogued as COSV61088550, COSV61093090, COSV61093632; called by muse, mutect2, varscan2
- LRRC52 | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 121/450 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV54233317; called by muse, mutect2, varscan2
- MACF1 | c.3394C>T p.R1132C | Missense Mutation (SNP) | VAF 69/405 reads (17%) | catalogued as rs62623398; called by muse, mutect2, varscan2
- NR1H3 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 120/502 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.139); catalogued as rs200485609, COSV101269821; called by muse, varscan2
- PRSS54 | c.539C>T p.T180M | Missense Mutation (SNP) | VAF 56/276 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758697357; called by muse, mutect2
- SEPTIN9 | c.731C>G p.A244G (on ENST00000427177 / NM_001113491.2; = p.A226G on NM_006640.4) | Missense Mutation (SNP) | VAF 97/424 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV61206662; called by muse, varscan2
- SGSM1 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 97/422 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752638490; called by muse, mutect2, varscan2
- TRAF3IP1 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 67/344 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs372959878; called by muse, varscan2
- ZNF536 | c.3301G>A p.D1101N | Missense Mutation (SNP) | VAF 124/564 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as COSV62821636, COSV62837321; called by muse, varscan2
- KATNIP | c.2814G>T p.L938F | Missense Mutation (SNP) | VAF 134/628 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, varscan2
- LTBP4 | c.1072G>A p.V358M (on ENST00000308370 / NM_001042544.1; = p.V321M on NM_003573.2) | Missense Mutation (SNP) | VAF 130/628 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MAEL | c.1018G>T p.V340L | Missense Mutation (SNP) | VAF 93/392 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- MAP2K6 | c.632C>A p.T211K | Missense Mutation (SNP) | VAF 75/323 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCOA6 | c.2104C>T p.Q702* | Nonsense Mutation (SNP) | VAF 76/338 reads (22%) | called by muse, varscan2
- SLC1A6 | c.392C>A p.A131E | Missense Mutation (SNP) | VAF 103/522 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TRIM33 | c.2061+1G>T p.X687_splice | Splice Site (SNP) | VAF 70/284 reads (25%) | called by muse, varscan2
- WDSUB1 | c.264G>A p.M88I | Missense Mutation (SNP) | VAF 86/420 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, varscan2
- WIZ | c.211C>A p.Q71K | Missense Mutation (SNP) | VAF 116/533 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- XPO7 | c.2797A>G p.T933A | Missense Mutation (SNP) | VAF 76/349 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, varscan2
- ZNF367 | c.954dup p.G319Rfs*50 | Frame Shift Ins (INS) | VAF 145/708 reads (20%) | called by mutect2, pindel, varscan2
- BAMBI | c.474C>T p.P158= | Silent (SNP) | VAF 92/464 reads (20%) | called by muse, varscan2
- FTMT | c.453C>T p.D151= | Silent (SNP) | VAF 97/494 reads (20%) | catalogued as COSV58420725; called by muse, varscan2
- IGFALS | c.870G>A p.L290= | Silent (SNP) | VAF 155/652 reads (24%) | called by muse, varscan2
- MN1 | c.649C>T p.L217= | Silent (SNP) | VAF 153/814 reads (19%) | catalogued as rs1464948745; called by muse, varscan2
- TSHZ3 | c.41-28918G>T | Intron (SNP) | VAF 62/460 reads (13%) | called by muse, mutect2, varscan2
